BEATAML1.0 case 2429 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/f568f74a-f72a-46e4-a22b-7f77f9c8ccb1

Demographics
Sex at birth: female; Race: native hawaiian or other pacific islander; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Therapy related myeloid neoplasm: ICD-O-3 morphology code: 9920/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 30.7 years (11,205 days); Progression or recurrence: yes; ELN risk classification: Intermediate.

Biospecimens (5 samples)
- Samples BA2025D, BA2446D (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Samples BA2025R, BA2446R (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
- Sample BA3016D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
